National Lung Screening Trial (NLST) participant 105949 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 66 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 26): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 110 mA, display field of view 29 cm, reconstruction filter Toshiba FC51.
- T1 (day 390): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 100 mA, display field of view 30 cm, reconstruction filter Toshiba FC51.
- T2 (day 747): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 100 mA, display field of view 30 cm, reconstruction filter Toshiba FC51.

Abnormalities recorded by the reading radiologist on the CT screens (15 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation mixed; greatest diameter on CT slice 109.
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation mixed; greatest diameter on CT slice 125.
- T0 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T0 abnormality 4: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 124; pre-existing on earlier images (earliest visible day 26); no interval growth; no suspicious change in attenuation.
- T1 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 106; pre-existing on earlier images (earliest visible day 26); no interval growth; no suspicious change in attenuation.
- T1 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the lingula; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 83; pre-existing on earlier images (earliest visible day 26); no interval growth; no suspicious change in attenuation.
- T1 abnormality 4: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 5: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 115; pre-existing on earlier images (earliest visible day 26); interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 133; identified only on comparison with prior images; pre-existing on earlier images (earliest visible day 26); no interval growth; no suspicious change in attenuation.
- T2 abnormality 4: Other minor abnormality noted.
- T2 abnormality 5: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 4 mm, longest perpendicular diameter 2 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 68; pre-existing on earlier images (earliest visible day 26); no interval growth; no suspicious change in attenuation.
- T2 abnormality 6: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the lingula; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 90; identified only on comparison with prior images; pre-existing on earlier images (earliest visible day 26); no interval growth; no suspicious change in attenuation.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,276.
